TCGA case TCGA-X6-A7W8 — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Fibromatous Neoplasms; Primary site: Connective, subcutaneous and other soft tissues; Tissue source site: University of Iowa. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c849127a-2f15-4fab-8815-db09b017f48c

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age: 90 years or older (exact value withheld by GDC); Vital status: Dead; Days to death: 24 days.

Diagnoses (2)
1. Fibromyxosarcoma (the primary disease): ICD-O-3 morphology code: 8811/3; ICD-10 code: C49.2; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Site of resection or biopsy: Connective, subcutaneous and other soft tissues of lower limb and hip; Classification of tumor: primary; Age at diagnosis: 90 years or older (exact value withheld by GDC); Year of diagnosis: 2011; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Tumor focality: Unifocal.
   Pathology details: Measurement type: Radiologic; Tumor burden: 16.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 9; Tumor length measurement: 17.5; Tumor width measurement: 10.5.
   Pathology details: Measurement type: Pathologic; Tumor burden: 17.5.
   Pathology details: Consistent pathology review: Yes; Margin status: Involved; Necrosis percent: 30; Necrosis present: Yes; Tumor depth descriptor: Deep.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor depth measurement: 8; Tumor length measurement: 16; Tumor width measurement: 11.
2. Metastasis of diagnosis 1 (Fibromyxosarcoma), site: Lung, NOS. Age at diagnosis: 90 years or older (exact value withheld by GDC); Days to diagnosis: 24 days; Prior treatment: Yes; Tumor focality: Unifocal.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.

Follow-up (2 entries)
- Day 0 (initial diagnosis): Discontiguous lesion count: 1.
- Day 24 (post initial treatment): Disease response: With Tumor; Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 24 days.

Molecular and laboratory tests
- Test: Mitotic Count Reported; Mitotic count: 40.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-X6-A7W8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 250 mg.
  Slide TCGA-X6-A7W8-01A-02-TSB: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-X6-A7W8-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-X6-A7W8-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor.
- Primary pathology: Histologic diagnosis: Myxofibrosarcoma; Margin status: Positive; Tumor total necrosis: Moderate Necrosis (>=10, <50%); Disease multifocal indicator: No; Discontinuous lesions count: 1; Locoregional recurrence indicator: No; Metastatic disease confirmed: No.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Lower Extremity - Thigh/knee.
- Primary pathology, Tumor sizes, Tumor size: Lesion radiologic depth: 8; Lesion pathologic depth: 9.
- Radiation treatment: Radiation therapy type: External; Radiation total dose: 6600; Radiation adjuvant units: cGy; Radiation adjuvant fractions total: 33; Radiation therapy site: Primary Tumor Field; Radiation therapy ongoing indicator: No; Treatment best response: Complete Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 804 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 804 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 146 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-X6-A7W8-01A-21D-A350-01): tumor purity 0.67, ploidy 2.65, whole-genome doublings 1.
